Somatic mutation profile of tumor specimen TARGET-10-PASYCN-09A (aliquot TARGET-10-PASYCN-09A-01D) from TARGET case TARGET-10-PASYCN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.0 years (4,009 days).
Specimen TARGET-10-PASYCN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cde9ead5-ea4e-436d-a354-4280ba054ad3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASYCN-10A (Blood Derived Normal), aliquot TARGET-10-PASYCN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47d175a8-ce1e-4a88-9be9-7527c2263bce

The open-access MAF lists 37 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 6, Frame Shift Ins 3, Intron 3, 3'Flank 2, Nonsense Mutation 1, In Frame Ins 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 10/18 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKRD7 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV54555498, COSV54556590; called by muse, mutect2, varscan2
- DNM2 | c.1539del p.N514Ifs*7 (on ENST00000355667 / NM_001005360.3; = p.N514Ifs*3 on NM_004945.3) | Frame Shift Del (DEL) | VAF 86/162 reads (53%) | catalogued as COSV58973083; called by mutect2, pindel, varscan2
- EZH2 | c.2036G>A p.R679H (on ENST00000460911 / NM_001203247.2; = p.R684H on NM_004456.5) | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.183); catalogued as CM1312136, COSV57446629, COSV57448135; called by muse, mutect2, varscan2
- GAREM2 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs1273274722, COSV68226039; called by muse, mutect2, varscan2
- GRIA1 | c.2542C>A p.Q848K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.021); catalogued as COSV53611550; called by muse, mutect2, varscan2
- HYDIN | c.7574G>A p.R2525H | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs756437118, COSV59262649; called by muse, mutect2, varscan2
- ILF3 | c.1870G>A p.G624S | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as rs765717836, COSV51559653; called by muse, mutect2, varscan2
- LRP8 | c.2584G>T p.D862Y | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60097931, COSV60099664; called by muse, mutect2, varscan2
- MET | c.1772G>A p.R591Q | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as rs775965879, COSV100577302, COSV59264205; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NONO | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 22/24 reads (92%) | SIFT tolerated (0.34); PolyPhen benign (0.044); catalogued as COSV52138650; called by muse, mutect2, varscan2
- NOTCH1 | c.7356_7357insCGCTGGCG p.V2453Rfs*27 | Frame Shift Ins (INS) | VAF 7/21 reads (33%) | catalogued as COSV53029658; called by mutect2, pindel
- PDE12 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs142293870; called by muse, mutect2, varscan2
- PTEN | c.739_740insGGGCGT p.P246_L247insWA | In Frame Ins (INS) | VAF 10/24 reads (42%) | catalogued as COSV64300704, COSV64301510, COSV99058000; called by pindel, varscan2
- SAP130 | c.3130C>T p.R1044* | Nonsense Mutation (SNP) | VAF 25/56 reads (45%) | catalogued as rs745900627, COSV52099472; called by muse, mutect2, varscan2
- SH2B3 | c.1207C>T p.L403F | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57984547; called by muse, mutect2, varscan2
- TP63 | c.1582C>A p.P528T | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV53211595; called by muse, mutect2, varscan2
- TRPA1 | c.2313A>T p.K771N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.091); catalogued as COSV51566322, COSV51574863; called by mutect2, varscan2
- UGGT2 | c.4112G>A p.R1371H | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1203096176, COSV65076396; called by muse, mutect2
- ZBTB18 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); catalogued as rs1423296558, COSV62396368; called by muse, mutect2, varscan2
- ZNF445 | c.2599C>T p.R867C | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1358132186, COSV68539178; called by muse, mutect2, varscan2
- ARPP21 | c.200_201insTCTTGCCG p.S68Lfs*83 | Frame Shift Ins (INS) | VAF 9/26 reads (35%) | called by mutect2, pindel, varscan2
- SATB1 | c.255_256insCC p.A86Pfs*17 | Frame Shift Ins (INS) | VAF 24/52 reads (46%) | called by mutect2, pindel, varscan2
- SNPH | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDR97 | c.4846G>A p.A1616T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2
- ALDH3B1 | c.1026C>T p.I342= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs778103299, COSV50291628; called by muse, mutect2, varscan2
- ALOX15 | c.936G>A p.L312= | Silent (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- NCKAP5 | c.1824C>T p.A608= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs373377710, COSV100490974; called by muse, mutect2, varscan2
- PDLIM5 | c.942G>A p.P314= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as rs139902919; called by mutect2, varscan2
- SALL1 | c.3630C>T p.P1210= | Silent (SNP) | VAF 34/56 reads (61%) | catalogued as rs773228308, COSV51753242; called by muse, mutect2, varscan2
- TENM2 | c.5784C>T p.D1928= (on ENST00000518659 / NM_001122679.2; = p.D1689= on NM_001080428.3) | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs775819571; called by muse, mutect2, varscan2
- C21orf62 | chr21:32788910 G>C | 3'Flank (SNP) | VAF 11/16 reads (69%) | called by muse, mutect2, varscan2
- CSNK1D | chr17:82239995 C>T | 3'Flank (SNP) | VAF 10/14 reads (71%) | catalogued as rs563709789; called by muse, varscan2
- FAM193A | c.439-2785T>A | Intron (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2, varscan2
- MYO15A | c.3610-42del | Intron (DEL) | VAF 18/45 reads (40%) | catalogued as rs751285415, COSV52763450; called by mutect2, pindel, varscan2
- OR5F2P | n.365G>A | RNA (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- ZFHX4 | c.3093+97del | Intron (DEL) | VAF 8/16 reads (50%) | catalogued as rs751858242; called by mutect2, varscan2
